Somatic mutation profile of tumor specimen C3L-05678-59 (aliquot CPT0322890002) from CPTAC case C3L-05678, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 33.6 years (12,279 days).
Specimen C3L-05678-59: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5e715ea-c2cb-4232-84ea-7bc44862c722.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05678-50 (Buccal Cell Normal), aliquot CPT0322820003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/824140ad-906c-41e7-9823-8b8e4f6d5f4a

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.2860C>A p.P954T | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as COSV100383519; called by muse, mutect2, varscan2
- FLT3 | c.1352C>T p.S451F | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV54046796; called by muse, mutect2, varscan2
- PNPLA5 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.034); catalogued as rs1208915627; called by muse, mutect2, varscan2
- ZFX | c.2357G>A p.R786Q | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs748417793, COSV58447078; called by muse, mutect2, varscan2
- MTOR | c.5418T>G p.H1806Q | Missense Mutation (SNP) | VAF 110/308 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSC22D1 | c.334C>A p.Q112K | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF711 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF2B | c.555C>T p.Y185= | Silent (SNP) | VAF 74/239 reads (31%) | catalogued as rs369155067, COSV52132496; called by muse, mutect2, varscan2
- ATP2A3 | chr17:3924793 G>A | 3'Flank (SNP) | VAF 55/192 reads (29%) | catalogued as rs1800914; called by muse, mutect2, varscan2
